Somatic mutation profile of tumor specimen TCGA-AR-A5QQ-01A (aliquot TCGA-AR-A5QQ-01A-11D-A28B-09) from TCGA case TCGA-AR-A5QQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.0 years (24,841 days).
Specimen TCGA-AR-A5QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92c4134a-cde5-475a-9ee2-d306f11a1f6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A5QQ-10A (Blood Derived Normal), aliquot TCGA-AR-A5QQ-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a889c5da-d693-4ebb-9831-2c47e24e3f27

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 5, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACSL4 | c.134G>A p.R45K (on ENST00000340800 / NM_022977.2; = p.R4K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100539036, COSV61615199; called by muse, mutect2
- APBA2 | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.11); catalogued as COSV68795072; called by muse, mutect2, varscan2
- ARHGAP21 | c.3446T>C p.L1149P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57610732; called by muse, mutect2, varscan2
- ATAD3B | c.381T>A p.F127L (on ENST00000308647; = p.F233L on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100426607; called by muse, mutect2
- BNC2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV66156557; called by muse, mutect2, varscan2
- CHRFAM7A | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV55398190; called by mutect2, varscan2
- CLCA1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs965907873, COSV99322796; called by muse, mutect2, varscan2
- CNGA2 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); catalogued as COSV61706204; called by muse, mutect2, varscan2
- COL16A1 | c.2005C>G p.P669A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV99595384; called by mutect2, varscan2
- COL5A2 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100880769; called by muse, mutect2
- CPT1A | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55760574, COSV55761767; called by muse, mutect2, varscan2
- DDX5 | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99858258; called by muse, mutect2
- EHMT1 | c.3704G>C p.G1235A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV66044602, COSV66044907; called by muse, mutect2, varscan2
- EML5 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as rs1411052479, COSV61351766; called by muse, mutect2, varscan2
- GABRD | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV66081771; called by muse, mutect2, varscan2
- GALNT2 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs763766688, COSV64197347; called by muse, mutect2, varscan2
- GLUL | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59383283; called by muse, mutect2, varscan2
- GRHL2 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52548771, COSV52554397; called by muse, mutect2, varscan2
- GSG1L | c.632C>T p.P211L (on ENST00000447459 / NM_001109763.2; = p.P56L on NM_144675.2) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101093909, COSV66579903; called by muse, mutect2
- HPS3 | c.1990A>T p.R664W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56057373; called by muse, mutect2, varscan2
- HSPB11 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs751666876, COSV52041851; called by muse, mutect2, varscan2
- IQCE | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555990190, COSV58081796; called by muse, mutect2, varscan2
- KCNB2 | c.1953T>A p.F651L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.444); catalogued as COSV101579000; called by muse, mutect2
- LAMA1 | c.8984G>C p.G2995A | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV67544010; called by muse, mutect2, varscan2
- MAP4 | c.3131A>G p.N1044S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53142370; called by muse, mutect2
- MDN1 | c.13139G>T p.W4380L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV65529775; called by muse, mutect2, varscan2
- NYX | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV100699461; called by muse, mutect2
- PCDHA4 | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100793719, COSV63542709; called by muse, mutect2
- PCDHB11 | c.1220_1221del p.R407Tfs*36 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as rs575924242; called by pindel, varscan2
- PCDHB7 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50811703; called by muse, mutect2, varscan2
- PCSK5 | c.1108-1G>C p.X370_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65096010; called by muse, mutect2
- POGLUT1 | c.501G>C p.W167C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55158390; called by muse, mutect2, varscan2
- PPBP | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs772261845, COSV56020242; called by muse, mutect2, varscan2
- PSMC6 | c.575C>G p.T192R (on ENST00000612399; = p.T178R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV71628889; called by muse, mutect2, varscan2
- RANBP2 | c.6308G>C p.R2103T | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99313196; called by muse, mutect2
- RNPC3 | c.1406C>G p.A469G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166554367, COSV63716972; called by muse, mutect2, varscan2
- SMNDC1 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV100852184; called by muse, mutect2
- SOHLH1 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV53683827; called by muse, mutect2, varscan2
- SPEF2 | c.1945T>G p.L649V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV61550669; called by muse, mutect2, varscan2
- SPTLC2 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV53642935; called by muse, mutect2, varscan2
- STAB1 | c.5387G>A p.R1796Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs750335748, COSV58735036; called by muse, mutect2
- SVBP | c.72_73del p.K25Ifs*30 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs563737990; called by mutect2, pindel, varscan2
- TDRD5 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as COSV54249883; called by muse, mutect2, varscan2
- TPP2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV101060418; called by muse, mutect2
- TSPAN12 | c.36C>G p.C12W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV56081819; called by muse, mutect2, varscan2
- VRTN | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56443447; called by muse, mutect2, varscan2
- BIRC6 | c.10244A>G p.N3415S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.316); called by muse, mutect2
- CFAP44 | c.2268_2283dup p.F762Lfs*14 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- E2F3 | c.523_524del p.E175Kfs*5 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2869_2870del p.V957Cfs*14 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by pindel, varscan2
- FCGBP | c.12243G>C p.Q4081H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TYW1 | c.1274+2dup p.X425_splice | Splice Site (INS) | VAF 11/69 reads (16%) | called by mutect2, varscan2
- KDM3A | c.2898T>C p.F966= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs780870828, COSV57225482; called by muse, mutect2, varscan2
- KIAA1210 | c.3273C>A p.T1091= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV68179994; called by muse, mutect2, varscan2
- MTA2 | c.438G>A p.E146= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV53872961, COSV53874648; called by muse, mutect2, varscan2
- NALCN | c.2980C>T p.L994= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV51963577; called by muse, mutect2
- OR8K3 | c.345C>A p.L115= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57132963; called by muse, mutect2, varscan2
- PATJ | c.3447A>G p.G1149= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV57171539; called by muse, mutect2, varscan2
- RAPGEF2 | c.1665T>A p.I555= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100031614; called by muse, mutect2, varscan2
- SUGP2 | c.567G>C p.R189= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58264921; called by muse, mutect2, varscan2
- TDRD9 | c.3252C>T p.A1084= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs142825405; called by muse, mutect2, varscan2
- TENM1 | c.5187T>G p.T1729= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV64442108; called by muse, mutect2, varscan2
- TMCO4 | c.405A>G p.R135= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53877029; called by muse, mutect2, varscan2
- XYLT2 | c.1467C>T p.D489= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV50021570; called by muse, mutect2, varscan2
- HSP90AB1 | c.*125C>A | 3'UTR (SNP) | VAF 7/122 reads (6%) | catalogued as COSV99241396; called by muse, mutect2
